Somatic mutation profile of tumor specimen MP2PRT-PARXZS-TMP1-A (aliquot MP2PRT-PARXZS-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARXZS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.8 years (3,596 days).
Specimen MP2PRT-PARXZS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13038f48-b0e0-48c9-9749-7ac1683e0b01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXZS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXZS-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5923b7fb-84cf-4885-8ad5-c87eb9cc971b

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, In Frame Ins 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFP | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs367853668; called by muse, mutect2, varscan2
- ARHGAP21 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 102/261 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100256537, COSV57606906; called by muse, mutect2, varscan2
- CCDC8 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 224/596 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.871); called by muse, varscan2
- TP53I11 | c.414C>A p.C138* | Nonsense Mutation (SNP) | VAF 28/479 reads (6%) | called by muse, mutect2
- ZNF107 | c.945_946insGCT p.L315_T316insA | In Frame Ins (INS) | VAF 112/310 reads (36%) | called by mutect2, varscan2
- ZNF107 | c.946delinsGCTC p.T316delinsAP | In Frame Ins (INS) | VAF 126/348 reads (36%) | called by mutect2*, pindel, varscan2*
- ZNF766 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CLCN7 | c.657C>G p.P219= | Silent (SNP) | VAF 156/444 reads (35%) | catalogued as COSV99247551; called by muse, mutect2, varscan2
- FAM83H | c.2088G>A p.A696= | Silent (SNP) | VAF 372/947 reads (39%) | catalogued as COSV62027511; called by muse, mutect2, varscan2
- SHROOM1 | c.2001G>A p.T667= | Silent (SNP) | VAF 293/705 reads (42%) | catalogued as rs756559203; called by muse, mutect2, varscan2
- IGKC | chr2:88861923 ins CT | 5'Flank (INS) | VAF 78/322 reads (24%) | called by mutect2, pindel*, varscan2
